Gene-level copy-number profile of tumor specimen TCGA-Q2-A5QZ-01A from TCGA case TCGA-Q2-A5QZ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 61.7 years (22,531 days).
Specimen TCGA-Q2-A5QZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.bc094b02-ea90-41fd-a259-39f4e1c3028a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-Q2-A5QZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/87bc6b4e-6394-4095-9940-2b832c5ad4a7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 21,590; copy number 2: 35,143; copy number 3: 2,402; copy number 4: 100; copy number 5: 44; copy number 6: 44; copy number 7: 244; copy number 9: 116; copy number 11: 63; copy number 12: 70; copy number 13: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-Q2-A5QZ-01A-11D-A28F-01): tumor purity 0.7, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 585 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:119,223,831–126,203,372, 71 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr2:126,898,864–127,526,886, 21 genes, copy number 5: TEX51, RNU7-182P, AC012508.2, AC012508.3, AC012508.1, BIN1, AC110926.1, NIFKP9, CYP27C1, WBP11P2, ERCC3, AC068282.1, MAP3K2, RNU6-1147P, MAP3K2-DT, AC068282.2, PROC, MIR4783, IWS1, AC010976.1, RNU4-48P.
- chr2:181,076,051–182,131,398, 16 genes, copy number 6 (within-gene range 4–6): AC068196.1, LINC01934, MIR4437, AC020595.1, ITGA4, CERKL, NEUROD1, AC013733.2, AC013733.1, SAP18P2, RNU6ATAC19P, AC009962.1, ITPRID2, PPP1R1C, KRT18P29, RNA5SP113.
- chr2:187,001,876–197,786,762, 140 genes, copy number 5–13 (broad region; genes not listed).
- chr6:40,713,411–42,746,103, 63 genes, copy number 11 (broad region; genes not listed).
- chr6:43,040,777–60,546,660, 274 genes, copy number 5–13 (within-gene range 1–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 21,590. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
